TCGA case TCGA-A2-A0CX — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c744fc13-3aca-4245-9e24-abd368cc8bef

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,152 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 127 days; Number of cycles: 4; Treatment dose: 5,000 mg; Prescribed dose: 1250; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 127 days; Number of cycles: 4; Treatment dose: 504 mg; Prescribed dose: 126; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 148 days; Days to treatment end: 169 days; Number of cycles: 4; Treatment dose: 660 mg; Prescribed dose: 165; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 162 days; Days to treatment end: 367 days (1.0 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Goserelin Acetate; Days to treatment start: 601 days (1.6 years); Prescribed dose: 3.6; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 686 days (1.9 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 2.5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 1,184 days (3.2 years); Days to treatment end: 1,273 days (3.5 years); Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment end: 305 days; Course number: 1.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 1,303 days (3.6 years); Disease response: Tumor Free.
- Days to follow up: 1,728 days (4.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Positive; Staining intensity value: 3+.
- ESR1 (IHC): Positive.
- PGR (IHC): Negative; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A0CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 560 mg.
  Slide TCGA-A2-A0CX-01A-02-BSB: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A0CX-01A-02-TSB: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A0CX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A0CX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Her2 IHC score: 3+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 5; Pharmaceutical therapy drug name: Zoladex; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Given to induce menopause.
- Drug treatment 1, Route of administrations: Route of administration: IM.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 4: Regimen number: 3; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 5: Regimen number: 4; Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 6: Regimen number: 6.
- Drug treatment 6, Route of administrations: Route of administration: PO.
- Drug treatment 7: Regimen number: 7.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,728 days; disease-specific survival: no event (censored), 1,728 days; disease-free interval: no event (censored), 1,728 days; progression-free interval: no event (censored), 1,728 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A0CX-01A-21D-A011-01): tumor purity 0.45, ploidy 3.45, whole-genome doublings 1.
